Somatic mutation profile of tumor specimen TCGA-EJ-5522-01A (aliquot TCGA-EJ-5522-01A-01D-1576-08) from TCGA case TCGA-EJ-5522, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 51.5 years (18,802 days).
Specimen TCGA-EJ-5522-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd7f7464-c4dd-4890-a194-9d96c44dcc6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5522-10A (Blood Derived Normal), aliquot TCGA-EJ-5522-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73d41d86-f63b-49bb-b6cf-4c8a3b76980e

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 8, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASCC3 | c.2017G>T p.D673Y | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61229916; called by muse, mutect2, varscan2
- ASPHD2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 53/274 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780604426, COSV53217925; called by muse, mutect2, varscan2
- CELF2 | c.931G>A p.A311T (on ENST00000416382 / NM_001025077.3; = p.A318T on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.163); catalogued as rs557804153, COSV59976437; called by muse, mutect2, varscan2
- CYP21A2 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs72552755, CM970412, COSV64480176; called by muse, mutect2, varscan2
- DAPK1 | c.3822dup p.Y1275Vfs*64 | Frame Shift Ins (INS) | VAF 24/120 reads (20%) | catalogued as rs779681511; called by mutect2, varscan2
- FAM83G | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs778257113, COSV58759120; called by muse, mutect2, varscan2
- FIGN | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 90/332 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV60768075; called by muse, mutect2, varscan2
- OR8J1 | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.084); catalogued as COSV57318811; called by muse, mutect2, varscan2
- PIWIL3 | c.1381G>T p.D461Y | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59996211; called by muse, mutect2, varscan2
- PRAM1 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.242); catalogued as COSV55314366; called by muse, mutect2, varscan2
- ROBO2 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778684665, COSV59899211; called by muse, mutect2, varscan2
- SECISBP2L | c.148A>T p.I50F | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55935151, COSV55935551; called by muse, mutect2, varscan2
- ANK1 | c.1614C>T p.T538= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as rs1302136186, COSV55884474; called by muse, mutect2, varscan2
- CCNL2 | c.420C>T p.R140= | Silent (SNP) | VAF 63/288 reads (22%) | catalogued as COSV61224315; called by muse, mutect2, varscan2
- DLGAP2 | c.1215G>A p.P405= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs373198112; called by muse, mutect2, varscan2
- LPO | c.1965C>T p.N655= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as rs768511505, COSV51858684; called by muse, mutect2, varscan2
- OCIAD1 | c.249T>C p.C83= | Silent (SNP) | VAF 40/181 reads (22%) | catalogued as COSV51901231; called by muse, mutect2, varscan2
- PCDHGA3 | c.1803C>T p.N601= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV53967587, COSV54005926; called by muse, mutect2, varscan2
- PCDHGA4 | c.699C>T p.R233= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV53967598; called by muse, mutect2, varscan2
- UTP20 | c.6706C>T p.L2236= | Silent (SNP) | VAF 64/310 reads (21%) | catalogued as COSV55379007; called by muse, mutect2, varscan2
- RBPMS | c.528+4922C>A | Intron (SNP) | VAF 30/150 reads (20%) | catalogued as rs376566256, COSV55124062; called by muse, mutect2, varscan2
